Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-8519, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-8519-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Peritoneal implant; excision:

Nodular fat necrosis, no tumor identified.
Intraoperative consultation corroborated.
Focal foreign body giant cell reaction.

B. Peritoneal implant; excision:

Nodular fat necrosis, no tumor identified.
Intraoperative consultation corroborated.
Focal foreign body giant cell reaction.

C. Head of pancreas, duodenum; Whipple resection:

Tumor Characteristics:

1. Histologic type: Adenocarcinoma.
2. Histologic grade: Moderately to poorly differentiated.
3. Tumor site: Pancreatic head.
4. Tumor size: 1.8 cm.
5. Microscopic tumor extension: Tumor is limited to the pancreas but does focally extend into the peripancreatic adipose tissue

Surgical Margin Status:

Surgical margins including pancreatic neck, common bile duct, duodenum, superior vena cava, retroperitoneal, and peripancreatic soft tissue are negative for tumor.

Lymph Node Status:

1. Total number of lymph nodes received: 9.
2. Total number of lymph nodes containing metastatic carcinoma: 0 (0/9).

Other:

1. Intraoperative consultation corroborated.
2. pTNM stage: pT1 N0.

D. Stomach; gastrectomy:

Chronic gastritis, no evidence of dysplasia or malignancy.
Extensive fat necrosis of the perigastric adipose tissue.

E. Small bowel; resection:

Small bowel with no significant histopathologic abnormality.

COMMENTS:

Histologic sections show invasive carcinoma composed of small nests of infiltrative malignant glands. The tumor is relatively limited in amount and is immediately adjacent to the pancreatic duct. All surgical margins and lymph nodes are negative for tumor. The specimens labeled as peritoneal implant (specimens A and B) as well as the perigastric adipose tissue show extensive fat necrosis but no evidence of metastatic tumor.

CLINICAL INFORMATION

[page 2 of 3]
CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: [REDACTED] with pancreatic mass.

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Peritoneal implant
- B. Peritoneal implant
- C. Head of pancreas and duodenum
- D. Stomach
- E. Small bowel

SPECIMEN DATA

GROSS DESCRIPTION:

A. First container A is labeled with the patient's name [REDACTED] 'peritoneal implant'. The specimen consists of a firm yellow-gray portion of soft tissue measuring 2.5 x 2.0 x 1.0 cm, displays slight adhesions and surface hemorrhage. On sectioning, the cut surface displays yellow-gray fibrous tissue consistent with probable fat necrosis. Representative section was examined at the time of surgery. Representative sections are submitted in cassettes [REDACTED] as follows: Frozen section, block 1; additional sections in blocks 2 and 3.

B. The second container B is labeled [REDACTED] 'peritoneal implant.' The specimen consists of a piece of firm yellow-gray soft tissue measuring 1.5 x 1.5 x 0.5 cm. The margin has been inked. The specimen is sectioned. The cut surface is yellow-gray with hemorrhage. Representative section was examined at the time of surgery. The remainder of specimen is entirely submitted in cassettes labeled [REDACTED] as follows: Frozen section, block 1; remainder of specimen in blocks 2 and 3.

C. The third container C is labeled with the patient's name [REDACTED] #3. The specimen consists of a segment of duodenum and attached pancreatic head measuring in total 14.0 x 9.0 x 6.5 cm. The segment of the duodenum measures 8.5 cm in length and 3.0 cm in diameter. The margins are stapled. The serosal surface of the bowel is gray-brown with adhesions. The bowel is opened. The mucosal surface of the small bowel is gray-tan to brown-tan with flattened mucosal folds. The ampulla of Vater is identified and is dilated. There is a stent visible within the common bile duct. The lumen of the common bile duct is dilated measuring up to 0.5 cm. A lesion at the ampulla of Vater cannot be grossly identified. The lumens of the pancreatic duct and common bile duct are both probed and are patent. The head of the pancreas measures 7.5 x 5.5 x 4.0 cm. Adjacent to the pancreatic duct is a firm area measuring approximately 1.8 cm. The margins have been inked at the time of surgery as follow: uncinate process has been inked black, the common bile duct has been inked green, the neck has been inked yellow, and superior vena cava has been inked blue. Sections from the margins from the uncinate process, duodenum, retroperitoneum, common bile duct neck and superior vena cava have been examined at the time of surgery, and frozen section was performed. The remainder of the soft tissue margins have been inked red. The pancreas is sectioned. The cut surface is firm, yellow-gray, lobular, has a slightly nodular appearance, however, a well defined mass is not identified. Sectioning through the soft tissue, there reveals seven probable lymph nodes that measure from 0.5 to 1.8 cm. Received with the specimen are three cassettes, one green, one yellow, one blue labeled [REDACTED] as follows: Frozen section from uncinate, block 1; common bile duct, block 2; neck, block 3; superior vena cava, block 4; abdominal margins in blocks 5 and 6; pancreatic margin of resection in block 7; sections taken from the soft tissue margins to the pancreas from superior, block 8; inferior, block 9; anterior, block 10; posterior, block 11; sections taken from the area of the ampulla, block 12; from the uninvolved colon, block 13; sections from firm fibrous area of the pancreas in blocks 14 through 17; lymph nodes submitted in total designated as follows: one probable lymph node bisected (superior pancreatic) block 18; one probable lymph node (inferior pancreatic) in block 19; one probable lymph node trisected in block 20; one probable lymph node bisected in block 21; two probable nodes in block 22; one probable node sectioned in blocks 23 through 25 (posterior pancreatic lymph nodes); one probable lymph node bisected (pancreatic duodenal) in block 26.

D. Received in formalin labeled [REDACTED] and #4 stomach is a 7.3 cm segment of stomach with a minimal amount of attached fibroadipose tissue. There is a staple line at one margin and the opposite margin is opened. The specimen cannot be oriented.

The serosa is smooth to shaggy and tan-red. The mucosa is tan-pink with the normal folds. No obvious mucosal masses are identified. The inner circumference ranges from 1.4 cm to 2.5 cm. The wall thickness ranges from 0.2 cm to 0.8 cm.

There are a few irregular tan firm tissues consistent with possible lymph node ranging from 0.5 x 0.4 x 0.2 cm to 1.1 x 0.8 x 0.5 cm. The remainder of the fibroadipose tissue has slightly granular pink-yellow areas.

The specimen is sectioned and representative sections are submitted as labeled: block 1-- stapled margin (en face); block 2-- opened margin (en face); blocks 3-5-- random mucosa; block 6-- three whole possible lymph nodes; block 7-- one possible lymph node, bisected; blocks 8 and 9-- granular fibroadipose tissue; blocks 10 and 11-- random fibroadipose tissue. The blocks are labeled [REDACTED]

E. Received in formalin labeled [REDACTED] and #5 small bowel is a 5.7 cm segment of small bowel. Both margins are stapled close and the specimen cannot be oriented.

The serosa is smooth and tan-pink. The mucosa is tan-pink with edematous folds. No mucosal lesions are identified. The inner circumference averages 6.1 cm and the wall thickness averages 0.6 cm. No mesentery is attached to the specimen therefore no lymph nodes are identified.

Also received in the same container is a 1.5 x 1.2 x 0.5 cm hard yellow calculus.

[page 3 of 3]
The specimen is sectioned and representative sections are submitted as labeled: block 1— proximal and distal margins (en face); blocks 2 and 3— random mucosa. The blocks are labeled

INTRA-OPERATIVE CONSULTATION:

FROZEN SECTION DIAGNOSES:

Parts A and B: Fibrosis/fat necrosis. No malignancy identified per Dr.

Part C: Adenocarcinoma: uncinata, SVC, CBD, neck margins negative per Dr.

Source: NCI Genomic Data Commons file 5040317b-aeaf-4e31-beca-0c481bc25a4c (TCGA-HZ-8519.7E85913B-33AF-4BB5-AF45-E6B11A996C33.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).